Somatic mutation profile of tumor specimen TCGA-4W-AA9S-01A (aliquot TCGA-4W-AA9S-01A-11D-A391-08) from TCGA case TCGA-4W-AA9S, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.9 years (25,545 days).
Specimen TCGA-4W-AA9S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2562547c-7d88-45e1-8ff4-d23faff4669d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4W-AA9S-10A (Blood Derived Normal), aliquot TCGA-4W-AA9S-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00326327-8da5-4226-a894-2e4e1d5acd45

The open-access MAF lists 58 somatic variants for this specimen: 38 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 18, Nonsense Mutation 7, Frame Shift Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKAR | c.1368G>A p.W456* | Nonsense Mutation (SNP) | VAF 27/85 reads (32%) | catalogued as COSV99854295; called by muse, mutect2, varscan2
- BMP3 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99261726; called by muse, mutect2, varscan2
- CAPS | c.49T>C p.S17P | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99222309; called by muse, mutect2, varscan2
- CDV3 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs145414395; called by muse, mutect2, varscan2
- DRD5 | c.1408C>G p.P470A | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV100431533; called by muse, mutect2, varscan2
- EXTL3 | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as COSV99594032; called by muse, mutect2, varscan2
- FOLR1 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 101/257 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV100398553; called by muse, mutect2, varscan2
- HMCN1 | c.10753C>T p.R3585* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as rs748287658, COSV54921875; called by muse, mutect2, varscan2
- HTR1E | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs201640439, COSV59507189, COSV59508679; called by muse, mutect2, varscan2
- KCNH7 | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.255); catalogued as COSV100036104; called by muse, mutect2, varscan2
- LAMB1 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as COSV99740561; called by muse, mutect2
- LCT | c.4976G>A p.R1659Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV51544471; called by muse, mutect2, varscan2
- LTBP4 | c.3497G>A p.R1166H (on ENST00000308370 / NM_001042544.1; = p.R1129H on NM_003573.2) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.866); catalogued as rs532824443, COSV99192942; called by muse, mutect2, varscan2
- MATN4 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | PolyPhen probably damaging (1); catalogued as COSV59215014; called by muse, mutect2, varscan2
- MYOCD | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as COSV58503895; called by muse, mutect2, varscan2
- NEIL3 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1419494369, COSV52813309; called by muse, mutect2, varscan2
- NF1 | c.6951G>A p.W2317* (on ENST00000358273 / NM_001042492.3; = p.W2296* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100647168; called by muse, mutect2, varscan2
- NLRP3 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); catalogued as rs772009059, COSV100276465, COSV60228880; called by muse, mutect2, varscan2
- NYAP2 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.225); catalogued as COSV56015052, COSV99796348; called by muse, mutect2, varscan2
- OR4K15 | c.908C>T p.T303M (on ENST00000305051; = p.T279M on NM_001005486.1) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs150969455, COSV59301119; called by muse, mutect2, varscan2
- OR52R1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as rs200440576; called by muse, mutect2, varscan2
- OR6Y1 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV100225388; called by muse, mutect2, varscan2
- PPL | c.5009C>A p.S1670Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99278077; called by muse, mutect2, varscan2
- SEMG1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs199672858, COSV54871705, COSV54872099; called by muse, mutect2, varscan2
- SLC18A3 | c.635G>C p.R212P | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs1414069827, COSV100339771, COSV60334934; called by muse, mutect2, varscan2
- SLC18A3 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV100340214; called by muse, mutect2, varscan2
- SQOR | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 55/167 reads (33%) | catalogued as rs752389844, COSV99525806; called by muse, mutect2, varscan2
- ST18 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs760960889, COSV99389445; called by muse, mutect2, varscan2
- TARS3 | c.2136T>G p.Y712* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100254654; called by muse, mutect2, varscan2
- TCF12 | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99977681; called by muse, mutect2, varscan2
- TIMD4 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs200184575, COSV50854542; called by muse, mutect2, varscan2
- TMEM132D | c.2168T>A p.L723* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV101242873; called by muse, mutect2, varscan2
- TOX4 | c.1727G>A p.G576D | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99398315; called by muse, mutect2, varscan2
- TTC3 | c.5679C>G p.H1893Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100695581; called by muse, mutect2, varscan2
- UMODL1 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs571308622, COSV101253316, COSV68577815; called by muse, mutect2, varscan2
- VRTN | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1208336612, COSV56441774; called by muse, mutect2
- ZFYVE26 | c.1960A>G p.K654E | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV100720453; called by muse, mutect2, varscan2
- PTPN4 | c.704_708del p.G235Dfs*9 | Frame Shift Del (DEL) | VAF 32/113 reads (28%) | called by mutect2, pindel, varscan2
- ARL4A | c.424T>C p.L142= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV100775928; called by muse, mutect2, varscan2
- ARSH | c.447C>T p.S149= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as rs766047245, COSV101139874; called by muse, varscan2
- DYNC1I1 | c.447C>T p.G149= | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as rs750057492, COSV100268477, COSV61469173; called by muse, mutect2, varscan2
- ESCO1 | c.138A>G p.K46= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV99332302; called by muse, mutect2, varscan2
- HCN1 | c.2640C>T p.D880= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as rs768551046, COSV57506534; called by muse, mutect2, varscan2
- HSPA13 | c.885C>G p.V295= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as COSV99580055; called by muse, mutect2
- IPO4 | c.31C>A p.R11= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs542303871, COSV55779868, COSV99938057; called by muse, varscan2
- KRTAP5-8 | c.321C>G p.S107= | Silent (SNP) | VAF 81/240 reads (34%) | catalogued as COSV101273136; called by muse, mutect2, varscan2
- MEFV | c.1768C>T p.L590= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99560915; called by muse, mutect2, varscan2
- OR4K5 | c.339G>T p.V113= | Silent (SNP) | VAF 64/182 reads (35%) | catalogued as COSV60002929; called by muse, mutect2, varscan2
- PTPRB | c.867C>G p.P289= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV54250456, COSV99717561; called by muse, mutect2, varscan2
- RALGAPA2 | c.3084C>T p.D1028= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs375329177; called by muse, mutect2, varscan2
- SEPHS1 | c.514C>T p.L172= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV100525868, COSV100525992; called by muse, mutect2, varscan2
- SHLD1 | c.87C>T p.Y29= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as rs148670343; called by muse, mutect2, varscan2
- SLC7A14 | c.267G>A p.V89= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV99200527; called by muse, mutect2, varscan2
- TAF6L | c.1338C>T p.A446= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs768309072, COSV99585219; called by muse, mutect2, varscan2
- ZNF468 | c.1008C>T p.F336= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as rs775750307, COSV54694060; called by muse, mutect2
- ZNF578 | c.1557T>G p.T519= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV101405058; called by muse, mutect2
- MICAL3 | c.2241+4621C>T | Intron (SNP) | VAF 11/53 reads (21%) | catalogued as rs766218358, COSV99261706; called by muse, mutect2, varscan2
- TRAT1 | c.*1C>G | 3'UTR (SNP) | VAF 28/62 reads (45%) | catalogued as COSV99849284; called by muse, mutect2, varscan2
